Surgical pathology report (de-identified scan), TCGA case TCGA-85-8352, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-8352-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

[REDACTED]

[REDACTED]		Case ID	Gross Description	Microscopic Description
[REDACTED]		[REDACTED]		

[page 2 of 4]
Diagnosis Details	Comments	Formatted Path Report
		LUNG TISSUE CHECKLIST Specimen type: Pneumectomy Tumor site: Lung Tumor size: 8 x 7 x 7 cm Histologic type: Squamous cell carcinoma Histologic grade: Poorly differentiated Tumor extent: Visceral pleura Other tumor nodules: Not specified Lymph nodes: 3/8 positive for metastasis (Intrathoracic 3/8) Lymphatic invasion: Not specified Venous invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: Right- upper

[page 3 of 4]
	ID	Excision Date

[page 4 of 4]
Laterality

Right-upper

Source: NCI Genomic Data Commons file 429080ba-3d2f-4629-a5ca-d2ba48c9bfc9 (TCGA-85-8352.CE4D6F68-1332-4DBF-AE7F-EC3E5C7CD790.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).